Somatic mutation profile of tumor specimen C3N-01947-02 (aliquot CPT0226030006) from CPTAC case C3N-01947, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.9 years (18,216 days).
Specimen C3N-01947-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c509c38-0d5f-4bf5-8d2c-1f7f956234c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01947-31 (Blood Derived Normal), aliquot CPT0226120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96ab518a-d23f-49f7-b9f8-30f1fe54487d

The open-access MAF lists 116 somatic variants for this specimen: 72 protein-altering or splice-affecting, 26 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 26, Intron 7, 3'UTR 5, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 3, 5'UTR 2, 5'Flank 2, Splice Region 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNG4 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 44/447 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047514; called by muse, mutect2, varscan2
- CD69 | c.437A>G p.K146R | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.036); catalogued as rs751119124; called by muse, mutect2
- DPYD | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 109/517 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs760485592, COSV64590526; called by muse, mutect2, varscan2
- GRM5 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1471625539, COSV59597532; called by muse, mutect2, varscan2
- IKBKE | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100898381, COSV65625753; called by muse, varscan2
- KIAA1109 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs368386353; called by muse, mutect2
- LHCGR | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs754675508, COSV54302413; called by muse, mutect2
- LILRA1 | c.1358A>T p.H453L | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs759994851, COSV52180779; called by muse, mutect2
- PCDHA12 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 158/1188 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56559525; called by muse, mutect2, varscan2
- PI4KB | c.1672C>T p.L558F (on ENST00000368873 / NM_001369623.1; = p.L570F on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745689241; called by muse, mutect2, varscan2
- PIK3R5 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.759); catalogued as rs1204060138; called by muse, mutect2
- PKN3 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs765041696; called by muse, mutect2, varscan2
- RBM33 | c.3375+8C>T | Splice Region (SNP) | VAF 18/252 reads (7%) | catalogued as rs1348394185; called by muse, mutect2
- RELN | c.6325C>T p.Q2109* | Nonsense Mutation (SNP) | VAF 64/376 reads (17%) | catalogued as COSV100634701; called by muse, mutect2, varscan2
- TAF6 | c.100_102del p.E34del | In Frame Del (DEL) | VAF 40/270 reads (15%) | catalogued as rs1354229817; called by pindel, varscan2
- TBC1D23 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV61367249, COSV61368619; called by muse, mutect2, varscan2
- TMEM198 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); catalogued as rs374243531; called by muse, mutect2
- TMPO | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs560525921, COSV99702014; ClinVar: uncertain significance; called by muse, mutect2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 44/238 reads (18%) | catalogued as rs587780067; called by pindel, varscan2
- TRMT10C | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.789); catalogued as rs771098507; called by muse, mutect2, varscan2
- WDFY4 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1337383099; called by muse, mutect2
- ZNF507 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.156); catalogued as rs769271924, COSV61333037; called by muse, mutect2
- ABCC1 | c.2002A>G p.I668V | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- AFF2 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ANKRD50 | c.3147_3148dup p.C1050Sfs*17 | Frame Shift Ins (INS) | VAF 29/253 reads (11%) | called by mutect2, pindel, varscan2
- ASB15 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.1438G>C p.G480R | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ATP7A | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2
- C9orf131 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 34/429 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CASP8 | c.534T>A p.Y178* (on ENST00000432109 / NM_033355.3; = p.Y210* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 34/450 reads (8%) | called by muse, mutect2
- CCNB1 | c.859A>C p.M287L | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CTBP1 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3H | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- EMILIN3 | c.1894G>C p.A632P | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- EP300 | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 33/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FUCA1 | c.1214A>G p.N405S | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2
- GIT1 | c.1166del p.D389Afs*33 | Frame Shift Del (DEL) | VAF 57/457 reads (12%) | called by mutect2, pindel, varscan2
- KAZALD1 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNK12 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF18A | c.32dup p.H11Qfs*14 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- KLHL20 | c.785T>G p.L262R | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KRT7 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- KRTAP5-5 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); called by muse, varscan2
- MAGED1 | c.1781+3A>G | Splice Region (SNP) | VAF 19/109 reads (17%) | called by muse, mutect2, varscan2
- MYOM1 | c.3658T>G p.S1220A | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NBPF6 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- NDUFS7 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 140/596 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NEK3 | c.413A>T p.N138I | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NID2 | c.3961del p.I1321Sfs*2 | Frame Shift Del (DEL) | VAF 43/278 reads (15%) | called by mutect2, pindel, varscan2
- NR3C1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NYAP2 | c.802T>C p.Y268H | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDZRN3 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2
- PIK3R5 | c.150G>C p.R50S | Missense Mutation (SNP) | VAF 34/357 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCE1 | c.4991A>T p.E1664V | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPP2R3C | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- RRP12 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 82/562 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RYR2 | c.9053G>A p.R3018K | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SNRNP200 | c.6332A>C p.D2111A | Missense Mutation (SNP) | VAF 57/436 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SREBF1 | c.442A>T p.S148C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- ST6GAL2 | c.646A>G p.M216V | Missense Mutation (SNP) | VAF 39/316 reads (12%) | PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TDRD12 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- TLL2 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by mutect2, varscan2
- TP63 | c.898A>C p.T300P | Missense Mutation (SNP) | VAF 96/463 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPO | c.1246C>A p.R416S | Missense Mutation (SNP) | VAF 44/588 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- UNC5C | c.2228T>G p.L743R | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- WNT10A | c.1100C>G p.A367G | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.158); called by muse, mutect2
- ZBTB47 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF142 | c.160_161dup p.E55Lfs*8 | Frame Shift Ins (INS) | VAF 14/132 reads (11%) | called by mutect2, pindel
- ZNF345 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 15/227 reads (7%) | called by muse, mutect2
- ZNF362 | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ZNF467 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- ZNF790 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2
- ASPM | c.72G>A p.L24= | Silent (SNP) | VAF 45/307 reads (15%) | catalogued as COSV54130482; called by muse, mutect2, varscan2
- CAB39 | c.960C>T p.N320= | Silent (SNP) | VAF 33/196 reads (17%) | catalogued as rs140484947; called by muse, mutect2, varscan2
- CTSG | c.690G>A p.R230= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- DIPK1A | c.1252T>C p.L418= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs756454205; called by muse, mutect2, varscan2
- GFAP | c.963G>A p.A321= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as rs749881380; called by muse, mutect2
- HCAR1 | c.756C>T p.C252= | Silent (SNP) | VAF 41/309 reads (13%) | catalogued as rs146760413; called by muse, mutect2, varscan2
- HYDIN | c.7593G>A p.A2531= | Silent (SNP) | VAF 44/280 reads (16%) | catalogued as rs185945967, COSV59253502; called by muse, mutect2, varscan2
- IQCG | c.567G>T p.S189= | Silent (SNP) | VAF 40/333 reads (12%) | called by muse, mutect2, varscan2
- IRS2 | c.1572C>T p.I524= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as rs1226222952; called by muse, mutect2
- LRP1B | c.11268A>T p.T3756= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs752632589; called by muse, mutect2, varscan2
- NLRC5 | c.1782T>C p.A594= | Silent (SNP) | VAF 67/566 reads (12%) | catalogued as rs1405386813; called by muse, mutect2, varscan2
- NLRC5 | c.4938C>T p.I1646= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- NNMT | c.30C>T p.T10= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs1197444061; called by muse, mutect2, varscan2
- NOBOX | c.1422C>T p.G474= | Silent (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- OR52I2 | c.951C>T p.T317= | Silent (SNP) | VAF 51/423 reads (12%) | catalogued as rs148544990; called by muse, mutect2, varscan2
- PI4KB | c.1671G>T p.R557= (on ENST00000368873 / NM_001369623.1; = p.R569= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/260 reads (11%) | called by muse, mutect2, varscan2
- PIGO | c.1488G>A p.A496= | Silent (SNP) | VAF 69/377 reads (18%) | catalogued as rs140004995; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXND1 | c.5373C>T p.I1791= | Silent (SNP) | VAF 64/339 reads (19%) | catalogued as COSV60710940; called by muse, mutect2, varscan2
- RAB3D | c.588C>T p.S196= | Silent (SNP) | VAF 26/210 reads (12%) | catalogued as rs774112638; called by muse, mutect2, varscan2
- RGS9BP | c.207C>T p.A69= | Silent (SNP) | VAF 24/396 reads (6%) | catalogued as rs375089183; called by muse, mutect2
- SLC25A35 | c.630G>T p.V210= | Silent (SNP) | VAF 65/242 reads (27%) | called by muse, mutect2, varscan2
- SLC35F6 | c.456C>T p.I152= | Silent (SNP) | VAF 71/470 reads (15%) | catalogued as rs779765702, COSV100733739; called by muse, mutect2, varscan2
- SLC9A3 | c.105G>A p.A35= | Silent (SNP) | VAF 18/315 reads (6%) | called by muse, mutect2
- SUSD4 | c.978G>A p.T326= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as rs780896543; called by muse, mutect2, varscan2
- TEX13B | c.708C>T p.C236= | Silent (SNP) | VAF 45/366 reads (12%) | catalogued as rs41300888; called by muse, mutect2, varscan2
- TLR6 | c.2097C>T p.I699= | Silent (SNP) | VAF 21/341 reads (6%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+38506G>A | Intron (SNP) | VAF 21/252 reads (8%) | catalogued as rs747646278; called by muse, mutect2
- CCDC136 | chr7:128791463 A>T | 5'Flank (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11435C>T | Intron (SNP) | VAF 37/302 reads (12%) | catalogued as rs760363819; called by muse, mutect2, varscan2
- FAM174B | c.*174G>A | 3'UTR (SNP) | VAF 99/498 reads (20%) | called by muse, mutect2, varscan2
- HCN1 | c.-23G>A | 5'UTR (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- KNCN | c.*87G>A | 3'UTR (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- KRT17P5 | n.1220G>A | RNA (SNP) | VAF 62/664 reads (9%) | called by muse, mutect2, varscan2
- LASP1 | c.*4C>T | 3'UTR (SNP) | VAF 18/300 reads (6%) | catalogued as rs375387659, COSV100530353; called by muse, mutect2
- MYLK2 | c.*26C>T | 3'UTR (SNP) | VAF 24/179 reads (13%) | catalogued as rs747851631; called by muse, mutect2, varscan2
- NPEPL1 | chr20:58691767 G>C | 5'Flank (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- NPHP3 | c.-39C>T | 5'UTR (SNP) | VAF 32/254 reads (13%) | called by muse, varscan2
- PAK5 | c.1483-22A>T | Intron (SNP) | VAF 28/146 reads (19%) | catalogued as rs540862715, COSV62035582; called by muse, mutect2, varscan2
- PHB2 | c.872+44_872+45insAATC | Intron (INS) | VAF 37/345 reads (11%) | called by mutect2, pindel, varscan2
- RGS12 | c.*1G>A | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- RGS20 | c.510+1395G>C | Intron (SNP) | VAF 69/366 reads (19%) | called by muse, mutect2, varscan2
- SLC38A6 | c.1196-22T>G | Intron (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- SLC39A4 | c.1474+27G>T | Intron (SNP) | VAF 105/600 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-9 | n.61C>T | RNA (SNP) | VAF 43/453 reads (9%) | catalogued as rs763161059; called by muse, mutect2, varscan2
